Gene-level copy-number profile of tumor specimen TCGA-D5-5541-01A from TCGA case TCGA-D5-5541, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 63.3 years (23,109 days).
Specimen TCGA-D5-5541-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.bd9f6277-60d1-42b9-ad06-3f6d2882a5a8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-5541-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7bbce78d-6420-49d9-8ab4-7ceba4a5b789

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,185; copy number 3: 241; copy number 4: 37,397; copy number 5: 3,690; copy number 6: 8,062; copy number 7: 4,383; copy number 8: 2; copy number 9: 176; copy number 10: 91; copy number 11: 179; copy number 12: 936; copy number 13: 16; copy number 15: 983; copy number 16: 125; copy number 17: 16; copy number 18: 199; copy number 19: 137.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-5541-01A-01D-1649-01): tumor purity 0.78, ploidy 2.37, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,858 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:51,259,429–57,773,381, 176 genes, copy number 9 (broad region; genes not listed).
- chr8:36,784,324–145,066,685, 1,709 genes, copy number 10–19 (broad region; genes not listed).
- chr20:24,297,585–64,313,132, 973 genes, copy number 15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
